Somatic mutation profile of tumor specimen TCGA-F5-6702-01A (aliquot TCGA-F5-6702-01A-11D-1826-10) from TCGA case TCGA-F5-6702, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.5 years (26,123 days).
Specimen TCGA-F5-6702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2fa94e2-a553-4717-afc9-a477a609b614.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6702-10A (Blood Derived Normal), aliquot TCGA-F5-6702-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91202814-4587-4225-afc9-12e4424554e9

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 40/114 reads (35%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV54032612; called by muse, mutect2, varscan2
- ADGRB1 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs755969656, COSV60093813; called by muse, mutect2, varscan2
- C10orf90 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.851); catalogued as rs201947519, COSV99505408; called by mutect2, varscan2
- C11orf65 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67596846, COSV67597315; called by muse, mutect2
- C2CD2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs571197268, COSV61599928; called by muse, mutect2, varscan2
- CERKL | c.256T>G p.L86V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100184282; called by mutect2, varscan2
- CLK1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.068); catalogued as rs140005351; called by muse, mutect2
- FBXL4 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.952); catalogued as COSV100014423; called by muse, mutect2
- FLG | c.7361C>T p.T2454M | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs553191250, COSV64241299, COSV64244954; called by muse, mutect2, varscan2
- FRY | c.5623C>T p.R1875W | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1344977163, COSV66571116; called by muse, mutect2, varscan2
- GABRQ | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs781893243, COSV64782702; called by muse, mutect2, varscan2
- GRIK3 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs570872316, COSV66141033; called by muse, mutect2, varscan2
- GRM7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761983302, COSV63151566; called by muse, mutect2, varscan2
- IGHV3-21 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs562543291; called by muse, mutect2, varscan2
- ITIH4 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs550860646, COSV56575920; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 50/188 reads (27%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRP1B | c.10082G>A p.R3361Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV67196916, COSV67285422; called by muse, mutect2, varscan2
- MAP3K2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV61295093; called by muse, mutect2
- MYH2 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1297360031, COSV55441726; called by muse, mutect2, varscan2
- NECAP2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV61433595; called by muse, mutect2, varscan2
- NID1 | c.3212C>T p.T1071M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs533832624, COSV51623485; called by muse, mutect2, varscan2
- OR7C1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756541110, COSV50183626; called by muse, mutect2, varscan2
- PLPPR4 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV64569125; called by muse, mutect2, varscan2
- PRKCG | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1235252410, COSV54727061; called by muse, mutect2, varscan2
- PTPRS | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as rs1568465790, COSV53625879; called by muse, mutect2
- RAMP3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs574497056, COSV54246881; called by mutect2, varscan2
- RSPH1 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99370746; called by muse, mutect2, varscan2
- RTN1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV50731541; called by muse, mutect2, varscan2
- SLC25A17 | c.713A>C p.N238T | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99610811; called by muse, mutect2, varscan2
- SNF8 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV51727168; called by muse, mutect2, varscan2
- SPTA1 | c.4713T>G p.C1571W | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63755963; called by muse, mutect2, varscan2
- STH | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 47/96 reads (49%) | catalogued as COSV52242535; called by muse, mutect2, varscan2
- SYCP2L | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs769335051, COSV51654905; called by muse, mutect2, varscan2
- SYT9 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59621091; called by muse, mutect2, varscan2
- TAL1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs774469518, COSV53747554; called by mutect2, varscan2
- TSKS | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 9/74 reads (12%) | catalogued as COSV55876549; called by muse, mutect2, varscan2
- TTC30B | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375228748; called by muse, mutect2, varscan2
- UGT2B10 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99608882; called by muse, mutect2, varscan2
- ZNF566 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs778761847, COSV101091212, COSV67574193; called by muse, mutect2, varscan2
- C11orf65 | c.504A>T p.R168S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EP400 | c.569_570del p.F190Cfs*73 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, varscan2
- MLLT6 | c.331_337del p.V111Mfs*26 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- ADAM22 | c.2451C>T p.D817= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV55981663; called by muse, mutect2
- AP2B1 | c.654C>T p.G218= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs757946926, COSV99251836; called by muse, mutect2, varscan2
- ASB2 | c.321A>G p.K107= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100279663; called by mutect2, varscan2
- CALCR | c.1347G>A p.A449= (on ENST00000649521 / NM_001164737.2; = p.A433= on NM_001742.4) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1355807949, COSV64005949; called by muse, mutect2, varscan2
- CRLF2 | c.159G>A p.R53= | Silent (SNP) | VAF 221/493 reads (45%) | catalogued as COSV67493900; called by muse, mutect2, varscan2
- DNAH9 | c.13062G>A p.S4354= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs768129965, COSV52358638; called by mutect2, varscan2
- EPHA5 | c.2208C>T p.I736= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV56643736; called by muse, mutect2, varscan2
- FASTKD2 | c.1776C>T p.F592= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV52699021; called by muse, mutect2, varscan2
- FAT2 | c.11139A>C p.S3713= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV55823545; called by muse, mutect2, varscan2
- FCGBP | c.9192G>A p.T3064= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as rs554943335; called by muse, mutect2
- GLI2 | c.3165G>A p.A1055= (on ENST00000361492 / NM_001374353.1; = p.A1072= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs557121635, COSV58045503, COSV58052580; called by muse, mutect2
- NHSL2 | c.1641G>A p.A547= (on ENST00000510661; = p.A913= on NM_001013627.2) | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as rs1348360882, COSV65452546; called by muse, mutect2, varscan2
- NRXN3 | c.1869C>T p.S623= (on ENST00000557594 / NM_001272020.2; = p.S1047= on NM_004796.6) | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs1278974973, COSV55333195; called by muse, mutect2, varscan2
- OR6C68 | c.336T>A p.L112= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV65563517; called by muse, mutect2, varscan2
- PICALM | c.375G>A p.R125= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV62671692; called by muse, mutect2, varscan2
- RAB7A | c.252C>T p.C84= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs778176566, COSV99414290; called by muse, mutect2, varscan2
- CDC20B | c.126+2042C>G | Intron (SNP) | VAF 20/124 reads (16%) | catalogued as COSV99697535; called by muse, varscan2
